TCGA case TCGA-12-3646 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Duke. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/e8e43a65-4ec8-4e07-a884-a6989eec28cc

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 59 years; Vital status: Dead; Days to death: 1,339 days (3.7 years).

Diagnoses (2)
1. Glioblastoma (the primary disease): ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 59.8 years (21,855 days); Year of diagnosis: 2005; Method of diagnosis: Excisional Biopsy; Prior treatment: No.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 24 days; Days to treatment end: 66 days; Treatment dose: 6,000 cGy; Number of fractions: 30; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 24 days; Days to treatment end: 66 days; Number of cycles: 1; Treatment dose: 5,670 mg; Prescribed dose: 75; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 90 days; Days to treatment end: 151 days; Number of cycles: 2; Treatment dose: 3,600 mg; Prescribed dose: 200; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Lomustine; Treatment intent type: Adjuvant; Days to treatment start: 151 days; Days to treatment end: 234 days; Number of cycles: 2; Treatment dose: 400 mg; Prescribed dose: 110; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Bevacizumab; Treatment intent type: Adjuvant; Days to treatment start: 248 days; Days to treatment end: 334 days; Treatment dose: 4,182 mg; Prescribed dose: 10; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Irinotecan Hydrochloride; Treatment intent type: Adjuvant; Days to treatment start: 248 days; Days to treatment end: 334 days; Number of cycles: 2; Treatment dose: 3,611 mg; Prescribed dose: 340; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 334 days; Days to treatment end: 403 days (1.1 years); Number of cycles: 2; Treatment dose: 3,500 mg; Prescribed dose: 200; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Lomustine; Treatment intent type: Adjuvant; Days to treatment start: 405 days (1.1 years); Days to treatment end: 488 days (1.3 years); Number of cycles: 2; Treatment dose: 380 mg; Prescribed dose: 110; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Initial disease status: Recurrent Disease; Days to treatment start: 1,063 days (2.9 years); Days to treatment end: 1,315 days (3.6 years); Number of cycles: 8; Treatment dose: 17,920 mg; Prescribed dose: 50; Prescribed dose units: mg; Route of administration: Oral.
2. Progression of diagnosis 1 (Glioblastoma). Age at diagnosis: 63.4 years (23,170 days); Days to diagnosis: 1,315 days (3.6 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 1,007 days (2.8 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Progressive Disease.

Follow-up (4 entries)
- Day 1,315 (post initial treatment): Disease response: With Tumor; Progression or recurrence: Yes; Days to progression: 1,315 days (3.6 years).
- Days to follow up: 1,339 days (3.7 years); Disease response: With Tumor.
- Karnofsky performance status: 80; Timepoint: Prior to Adjuvant Therapy.
- Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Timepoint: Post Initial Treatment.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-12-3646-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1.3; Intermediate dimension: 0.7; Shortest dimension: 0.2.
  Slide TCGA-12-3646-01A-01-BS1: Section location: Bottom; Percent tumor cells: 75; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 20; Percent stromal cells: 5.
  Slide TCGA-12-3646-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0.
- Sample TCGA-12-3646-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-12-3646-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Untreated primary (de novo) GBM; History lgg diagnosis of brain tissue: No; Tumor status: With tumor; History neoadjuvant treatment: No; Performance status timing: Pre-Adjuvant Therapy.
- Drug treatment 1: Pharmaceutical therapy drug name: Temodar; Therapy regimen: Recurrence.
- Drug treatment 1, Route of administrations: Route of administration: PO.
- Drug treatment 2: Pharmaceutical therapy drug name: Ccnu.
- Drug treatment 4: Pharmaceutical therapy drug name: CPT 11.
- Drug treatment 4, Route of administrations: Route of administration: IV.
- Drug treatment 5: Pharmaceutical therapy drug name: Avastin.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,339 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,339 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 1,315 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-12-3646-01A-01D-0911-01): tumor purity 0.95, ploidy 1.88, whole-genome doublings 0.
